Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VU, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VU-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Report Status: Final

Procedure Date:

ICD O-3

Mesothelioma, epithelioid
malignant 905213
Site: Left Pleura NOS C38.4
Q40 6/18/14

PATHOLOGIC DIAGNOSIS:

- A. LEFT PORT SITE #1:
Skin with scar, negative for tumor.
- B. LEFT SIXTH RIB:
Bone marrow with maturing trilineage hematopoiesis, negative for tumor.
- C. 2R:
Lymph node(s), negative for tumor.
- D. LEVEL 5:
Lymph node, negative for tumor.
- E. LEVEL 9:
Lymph node, negative for tumor.
- F. LEVEL 8:
Lymph node, negative for tumor.
- G. LEVEL 5 #2:
Lymph node, negative for tumor.
- H. LEVEL 4L:
Lymph node(s), negative for tumor.
- I. LEVEL 10:
Lymph node, negative for tumor.
- J. LEFT PLEURA AND DIAPHRAGM:
MALIGNANT MESOTHELIOMA, epithelioid type, involving fibroadipose tissue
and skeletal muscle.
No lymphovascular invasion identified.
Specimen fragmentation precludes evaluation of margins.

TISSUE SUBMITTED:

- A/1. Left port site #1.
- B/2. Left sixth rib.
- C/3. 2R.
- D/4. Level 5.
- E/5. Level 9.
- F/6. Level 8.
- G/7. Level 5 #2.
- H/8. Level 4L.
- I/9. Level 10.
- J/10. Left pleura and diaphragm.

[page 2 of 3]
Pathology Report

GROSS DESCRIPTION:

The specimen is received fresh, in ten parts, each labeled with the patient's name and medical record number.

Part A, "#1. Left port site #1", consists of a tan/white skin ellipse (4 x 1.5 cm), excised to a depth of 2 cm, with a well-healed linear scar (2 cm in length). The deep aspect of the specimen contains a firm tan tissue (2 x 1.2 x 1 cm). The outer aspect of the specimen is inked blue. Representative sections are submitted for histologic evaluation.

Micro A1 and A2: 1 frag, RSS.

Part B, "#2. Left sixth rib", consists of a single portion of tan/pink rib (13.5 x 1.4 x 0.7 cm). Bone marrow squeeze is performed.

Micro B1: Bone marrow squeeze, multi frags, RSS.

Part C, "#3. 2R", consists of two fragment of yellow/brown soft tissue (1.6 x 1.0 x 0.8 and 1.2 x 0.5 x 0.5 cm) consistent with lymph nodes. Entire specimen is submitted for histologic evaluation. Larger node is inked red and bisected prior to submitting.

Micro C1: 2 lymph nodes, one inked and bisected, 3 frags, ESS.

Part D, "#4. Level 5", consists of a single fragment of tan/anthracotic soft tissue (0.6 x 0.5 x 0.3 cm), which is entirely submitted for histologic evaluation.

Micro D1: 1 frag, ESS.

Part E, "#5. Level 9", consists of a single fragment of tan/yellow/anthracotic soft tissue (1.0 x 0.8 x 0.4 cm) consistent with a lymph node. The specimen is entirely submitted for histologic evaluation.

Micro E1: 1 lymph node, 1 frag, ESS.

Part F, "#6. Level 8", consists of a single fragment of yellow/anthracotic soft tissue (0.9 x 0.3 x 0.2 cm), which is entirely submitted for histologic evaluation.

Micro F1: 1 frag, ESS.

Part G, "#7. Level 5 #2", consists of a single fragment of yellow/brown/anthracotic soft tissue (2.0 x 1.1 x 0.6 cm) grossly consistent with one lymph node. Entire specimen is submitted for histologic evaluation.

Micro G1: 1 lymph node, bisected, 2 frags, ESS.

Part H, "#8. Level 4L", consists of a single fragment of yellow/brown soft tissue (1.5 x 1.3 x 0.9 cm) grossly consistent with two lymph nodes (ranging from 0.2 to 0.9 cm in greatest dimension). Larger lymph node is inked blue and bisected prior to submitting. Entire specimen is submitted for histologic evaluation.

Micro H1: 2 lymph nodes, larger inked blue and bisected, and fibroadipose, 3 frags, ESS.

Part I, "#9. Level 10", consists of a single fragment of tan/anthracotic soft tissue (0.9 x 0.4 x 0.3 cm) consistent with a lymph node. Entire specimen is submitted for histologic evaluation.

Micro I1: 1 lymph node, 1 frag, ESS.

Part J, labeled "#10. Left pleura and diaphragm", consists of multiple fragments of tan/pink papillary soft tissue, tan/yellow lobulated fat and tan/red muscular soft tissue (21 x 18 x 2.8 cm; 430-gram in aggregate) with extensive firm, tan/white tumor. Representative sections of tan/pink papillary

[page 3 of 3]
Pathology Report

soft tissue is submitted for cytogenetics, tissue bank and
Representative sections are submitted for histologic evaluation.

Micro J1-J3: Papillary tissue to skeletal muscle, 1 frag each, RSS.

Micro J4-J8: Papillary soft tissue, 1-2 frags each, RSS.

Micro J9: Yellow adipose tissue, 2 frags, RSS.

[REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she
personally conducted a microscopic examination ("gross only" exam if so stated)
of the described specimen(s) and rendered or confirmed the diagnosis(es)
related thereto.

[REDACTED]

Source: NCI Genomic Data Commons file ad0cf268-7254-43f4-aa1f-b0ec8861b51f (TCGA-ZN-A9VU.671AF4AB-2F31-4C7B-AA46-B066EE103CF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).